Somatic mutation profile of tumor specimen TCGA-59-2372-01A (aliquot TCGA-59-2372-01A-01D-1526-09) from TCGA case TCGA-59-2372, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G2.
Specimen TCGA-59-2372-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a98347c9-8e21-4287-b871-4e76cada6f79.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-59-2372-10A (Blood Derived Normal), aliquot TCGA-59-2372-10A-01D-1526-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3a6601a6-0362-460f-8697-b717a93d4b15

The open-access MAF lists 91 somatic variants for this specimen: 71 protein-altering or splice-affecting, 19 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 64, Silent 19, Splice Site 3, Nonsense Mutation 2, Frame Shift Del 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 96/103 reads (93%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABHD11 | c.345C>G p.S115R | Missense Mutation (SNP) | VAF 117/461 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as COSV56105273; called by muse, mutect2, varscan2
- ACTL7A | c.80C>T p.A27V | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as COSV61776289; called by muse, mutect2, varscan2
- ACVRL1 | c.140G>A p.R47Q | Missense Mutation (SNP) | VAF 40/210 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs774389618, CM060789, COSV66359608; called by muse, mutect2, varscan2
- ADAMTS20 | c.2819A>T p.Q940L | Missense Mutation (SNP) | VAF 95/472 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV67127015; called by muse, mutect2, varscan2
- ADAMTS7 | c.3534G>T p.R1178S | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.6); PolyPhen benign (0.026); catalogued as COSV66306072; called by muse, mutect2, varscan2
- ADARB1 | c.319C>G p.P107A | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100654110; called by muse, mutect2
- ARID4B | c.2526G>C p.K842N | Missense Mutation (SNP) | VAF 41/230 reads (18%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.006); catalogued as COSV51598761; called by muse, mutect2, varscan2
- BRWD1 | c.324G>C p.R108S | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); catalogued as COSV58122340, COSV58123827; called by muse, mutect2, varscan2
- BTN3A3 | c.1031T>C p.L344P | Missense Mutation (SNP) | VAF 39/192 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55070980; called by muse, mutect2, varscan2
- CACNG7 | c.209G>A p.G70D | Missense Mutation (SNP) | VAF 132/275 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.791); catalogued as COSV55813125, COSV55814330; called by muse, mutect2, varscan2
- CAMTA1 | c.928G>C p.E310Q | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV57883507; called by muse, mutect2, varscan2
- CATSPER2 | c.157C>A p.Q53K | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.48); PolyPhen benign (0.406); catalogued as COSV58660302; called by muse, varscan2
- CDC16 | c.1554G>C p.M518I | Missense Mutation (SNP) | VAF 147/327 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV52957967; called by muse, mutect2, varscan2
- CPNE1 | c.500A>T p.Q167L (on ENST00000352393; = p.Q172L on NM_003915.5) | Missense Mutation (SNP) | VAF 105/239 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV58290019; called by muse, mutect2, varscan2
- CTAG2 | c.26G>A p.G9E | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.917); catalogued as COSV55994138; called by muse, mutect2
- CTSO | c.136-1G>A p.X46_splice | Splice Site (SNP) | VAF 10/43 reads (23%) | catalogued as COSV70808840; called by muse, mutect2, varscan2
- DENND1A | c.1977G>T p.K659N | Missense Mutation (SNP) | VAF 105/118 reads (89%) | SIFT tolerated (0.08); PolyPhen benign (0.42); catalogued as COSV65347613; called by muse, mutect2, varscan2
- DNAH9 | c.2894G>A p.R965Q | Missense Mutation (SNP) | VAF 71/164 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); catalogued as rs768827013, COSV52335913, COSV52381288; called by muse, mutect2, varscan2
- DNAJA3 | c.22C>A p.R8S | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV52160861; called by muse, mutect2, varscan2
- EEA1 | c.371C>G p.A124G | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0.01); catalogued as COSV59282922; called by muse, mutect2, varscan2
- EXO1 | c.1454C>T p.T485I | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as COSV100799787, COSV62216515; called by muse, mutect2, varscan2
- FLT3 | c.1285A>G p.K429E | Missense Mutation (SNP) | VAF 48/128 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV54045589; called by muse, mutect2, varscan2
- GAPDH | c.511G>C p.V171L | Missense Mutation (SNP) | VAF 45/254 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.026); catalogued as COSV57520541; called by muse, mutect2, varscan2
- GBP4 | c.1100T>C p.L367P | Missense Mutation (SNP) | VAF 53/281 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63253060; called by muse, mutect2, varscan2
- HAPLN1 | c.965G>T p.R322I | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57145622, COSV99165050; called by muse, mutect2, varscan2
- HAS3 | c.1274C>T p.T425I | Missense Mutation (SNP) | VAF 111/484 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV54706019; called by muse, mutect2, varscan2
- IPCEF1 | c.1079G>T p.R360L | Missense Mutation (SNP) | VAF 89/101 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV54540898; called by muse, mutect2, varscan2
- KCNH5 | c.1883C>T p.A628V | Missense Mutation (SNP) | VAF 175/191 reads (92%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.937); catalogued as rs761541451, COSV59753321; called by muse, mutect2, varscan2
- KREMEN2 | c.37C>G p.L13V | Missense Mutation (SNP) | VAF 32/164 reads (20%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.006); catalogued as COSV53555490; called by muse, mutect2, varscan2
- KRT83 | c.836T>C p.I279T | Missense Mutation (SNP) | VAF 187/953 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.297); catalogued as rs761179648, COSV53338644; called by muse, mutect2, varscan2
- LATS2 | c.2688G>A p.W896* | Nonsense Mutation (SNP) | VAF 110/245 reads (45%) | catalogued as COSV66873759; called by muse, mutect2, varscan2
- LRRC27 | c.513G>C p.W171C | Missense Mutation (SNP) | VAF 30/366 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100689930; called by muse, mutect2
- MAVS | c.1158+2T>G p.X386_splice | Splice Site (SNP) | VAF 35/154 reads (23%) | catalogued as COSV63926486, COSV63927643; called by muse, mutect2, varscan2
- MUC17 | c.6037A>G p.S2013G | Missense Mutation (SNP) | VAF 189/851 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV60281111; called by muse, mutect2, varscan2
- MYOM2 | c.2698G>C p.D900H | Missense Mutation (SNP) | VAF 87/264 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.866); catalogued as rs779691808, COSV50702999; called by muse, mutect2, varscan2
- NFAT5 | c.1178C>G p.A393G | Missense Mutation (SNP) | VAF 64/304 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as COSV63025417; called by muse, mutect2, varscan2
- NFATC4 | c.2257G>T p.G753W | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.945); catalogued as COSV51597051; called by muse, mutect2, varscan2
- OPN5 | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 75/368 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.411); catalogued as rs1370710652, COSV55244312; called by muse, mutect2, varscan2
- PCNX1 | c.4106A>G p.N1369S | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.097); catalogued as rs761044717, COSV53089916; called by muse, mutect2, varscan2
- PITX1 | c.793G>A p.G265S | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs141612135, COSV99530734; called by muse, mutect2, varscan2
- PLCB4 | c.2216G>T p.R739L | Missense Mutation (SNP) | VAF 59/351 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV53794115, COSV53794279; called by muse, mutect2, varscan2
- PLXNA2 | c.4129A>C p.S1377R | Missense Mutation (SNP) | VAF 40/199 reads (20%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.966); catalogued as COSV65437969; called by muse, mutect2, varscan2
- PNMA8B | c.917C>T p.P306L | Missense Mutation (SNP) | VAF 42/47 reads (89%) | SIFT tolerated (0.19); PolyPhen benign (0.014); catalogued as rs779584054, COSV66535837; called by muse, mutect2, varscan2
- POGLUT2 | c.86C>T p.P29L | Missense Mutation (SNP) | VAF 246/270 reads (91%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.936); catalogued as rs949985921, COSV57278501; called by muse, mutect2, varscan2
- PRKG1 | c.1768G>T p.D590Y | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64766861; called by muse, mutect2, varscan2
- PYGO2 | c.649C>T p.Q217* | Nonsense Mutation (SNP) | VAF 10/134 reads (7%) | catalogued as COSV100868978; called by muse, mutect2
- ROR1 | c.1768G>A p.G590R | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.263); catalogued as rs374512783; called by muse, mutect2, varscan2
- SARDH | c.326C>T p.T109M | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767872616, COSV53832167; called by muse, mutect2, varscan2
- SERPINE2 | c.13C>G p.L5V | Missense Mutation (SNP) | VAF 58/223 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV51455937, COSV99296702; called by muse, mutect2, varscan2
- SHROOM3 | c.5789C>T p.T1930M | Missense Mutation (SNP) | VAF 59/120 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.356); catalogued as rs759206697, COSV56023824; called by muse, mutect2, varscan2
- SLC29A4 | c.790C>T p.R264W | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.91); catalogued as rs753124934, COSV51873024, COSV99786604; called by muse, mutect2, varscan2
- SLC2A6 | c.475G>C p.E159Q | Missense Mutation (SNP) | VAF 70/155 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64141865, COSV64142505; called by muse, mutect2, varscan2
- SLC35F5 | c.925G>A p.G309R | Missense Mutation (SNP) | VAF 146/208 reads (70%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.967); catalogued as COSV55517039; called by muse, mutect2, varscan2
- SLC36A3 | c.212G>A p.G71D | Missense Mutation (SNP) | VAF 111/377 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1007315457, COSV58855704; called by muse, mutect2, varscan2
- SLC7A2 | c.62C>T p.T21I (on ENST00000494857 / NM_001370338.1; = p.T61I on NM_003046.6) | Missense Mutation (SNP) | VAF 83/326 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.129); catalogued as rs943903171, COSV50247940; called by muse, mutect2, varscan2
- SMARCD3 | c.1173+1G>T p.X391_splice (on ENST00000262188 / NM_001003801.2; = p.X378_splice on NM_003078.4) | Splice Site (SNP) | VAF 111/570 reads (19%) | catalogued as COSV50389187; called by muse, mutect2, varscan2
- SPAM1 | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 23/150 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.169); catalogued as rs770976726, COSV56141288; called by muse, mutect2, varscan2
- SPG11 | c.3400T>G p.C1134G | Missense Mutation (SNP) | VAF 69/268 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV55991367; called by muse, mutect2, varscan2
- STK26 | c.155T>G p.I52S | Missense Mutation (SNP) | VAF 72/140 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV61228892; called by muse, mutect2, varscan2
- TNFSF11 | c.895C>G p.L299V | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.998); catalogued as COSV53476566; called by muse, mutect2, varscan2
- TOR1AIP1 | c.562G>T p.D188Y | Missense Mutation (SNP) | VAF 79/254 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV54868510; called by muse, mutect2, varscan2
- TOR3A | c.846G>C p.E282D | Missense Mutation (SNP) | VAF 31/174 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.07); catalogued as COSV61679753; called by muse, mutect2, varscan2
- TRMT1L | c.985G>T p.V329L | Missense Mutation (SNP) | VAF 62/205 reads (30%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV62271744; called by muse, mutect2, varscan2
- TSGA10 | c.2073G>C p.E691D | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.801); catalogued as COSV61822157; called by muse, mutect2, varscan2
- UFC1 | c.208T>G p.W70G | Missense Mutation (SNP) | VAF 39/142 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57086945; called by muse, mutect2, varscan2
- USP13 | c.1327A>G p.N443D | Missense Mutation (SNP) | VAF 24/821 reads (3%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV99831710; called by muse, mutect2
- UTRN | c.2869C>G p.L957V | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.14); PolyPhen benign (0.049); catalogued as COSV62329184; called by muse, mutect2, varscan2
- VWA5A | c.985T>C p.Y329H | Missense Mutation (SNP) | VAF 50/214 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV63707219; called by muse, mutect2, varscan2
- SLIT1 | c.1687_1691delinsC p.K563Lfs*4 | Frame Shift Del (DEL) | VAF 70/302 reads (23%) | called by pindel, varscan2*
- TUBA1B | c.332del p.G111Afs*71 | Frame Shift Del (DEL) | VAF 135/813 reads (17%) | called by mutect2, pindel, varscan2
- ADD2 | c.33G>A p.S11= | Silent (SNP) | VAF 45/195 reads (23%) | catalogued as COSV52455478; called by muse, mutect2, varscan2
- ANK1 | c.4206G>A p.Q1402= | Silent (SNP) | VAF 743/1032 reads (72%) | catalogued as COSV55873888; called by muse, mutect2, varscan2
- AP1B1 | c.2124C>T p.G708= | Silent (SNP) | VAF 118/126 reads (94%) | catalogued as rs745811408, COSV58014875; called by muse, mutect2, varscan2
- AP3B1 | c.939T>G p.A313= | Silent (SNP) | VAF 17/72 reads (24%) | catalogued as COSV54876998; called by muse, mutect2, varscan2
- CLCN5 | c.1257G>A p.P419= | Silent (SNP) | VAF 45/123 reads (37%) | catalogued as rs782232880, COSV56582542; called by muse, mutect2, varscan2
- CPD | c.2619C>A p.S873= | Silent (SNP) | VAF 29/83 reads (35%) | catalogued as COSV56710924, COSV56714082; called by muse, mutect2, varscan2
- DDX17 | c.2148A>G p.Q716= | Silent (SNP) | VAF 153/162 reads (94%) | catalogued as rs1386429085, COSV53246666; called by muse, mutect2, varscan2
- GDF2 | c.1140G>A p.V380= | Silent (SNP) | VAF 95/349 reads (27%) | called by muse, mutect2, varscan2
- GPD2 | c.111G>A p.L37= | Silent (SNP) | VAF 23/97 reads (24%) | catalogued as COSV60090440; called by muse, mutect2, varscan2
- IDH3A | c.195G>A p.E65= | Silent (SNP) | VAF 41/219 reads (19%) | catalogued as COSV55112083; called by muse, mutect2, varscan2
- KCNJ9 | c.939C>T p.G313= | Silent (SNP) | VAF 7/116 reads (6%) | catalogued as COSV100081819; called by muse, mutect2
- KMT5A | c.930C>T p.H310= | Silent (SNP) | VAF 140/824 reads (17%) | catalogued as rs200452780, COSV57862389; called by muse, mutect2, varscan2
- KRT6B | c.1140G>A p.E380= | Silent (SNP) | VAF 55/1304 reads (4%) | catalogued as COSV99360968; called by muse, mutect2
- MACF1 | c.19551G>A p.L6517= (on ENST00000372915; = p.L4562= on NM_012090.5) | Silent (SNP) | VAF 20/258 reads (8%) | catalogued as rs1336792385, COSV57125353; called by muse, mutect2
- NDRG4 | c.294C>T p.S98= (on ENST00000570248 / NM_001378344.1; = p.S130= on NM_020465.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 28/139 reads (20%) | catalogued as rs762810826, COSV50746596; called by muse, mutect2, varscan2
- OR10H1 | c.870C>T p.I290= | Silent (SNP) | VAF 168/336 reads (50%) | catalogued as COSV58470796; called by muse, mutect2, varscan2
- PCDH15 | c.1350A>T p.S450= | Silent (SNP) | VAF 28/304 reads (9%) | catalogued as COSV57267469, COSV57306517; called by muse, mutect2
- TMC2 | c.1047C>T p.F349= | Silent (SNP) | VAF 30/655 reads (5%) | catalogued as rs761808632, COSV100727559, COSV62653969; called by muse, mutect2
- ZNF107 | c.561C>T p.P187= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as COSV61327004; called by muse, mutect2, varscan2
- MAP2 | c.4585-1089A>T | Intron (SNP) | VAF 24/211 reads (11%) | catalogued as COSV52282418; called by muse, mutect2, varscan2
